Surgical pathology report (de-identified scan), TCGA case TCGA-59-2349, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Roswell Park, specimen TCGA-59-2349-01A (Primary Tumor).

[page 1 of 4]
Name:
Address:

Service:

Pathology No.:

CLINICAL HISTORY:

old [redacted] with mass upper pole left kidney and left pelvic mass. s/p [redacted] rectomy and right oophorectomy in [redacted] Exc. liposarcoma left chest wall [redacted] and [redacted], also bx. [redacted] colon cancer

Does the patient have:

Yes No Unknown

Previous
Previous
Previous

X
X
X
X
X

PRE-OPERATIVE DIAGNOSIS AND DIFFERENTIAL:
Left renal tumor and left pelvic mass

POST-OPERATIVE DIAGNOSIS: [redacted]

SPECIFIC QUESTIONS TO BE ANSWERED BY CONSULTATION (if any): [redacted]

OPERATION: [redacted]

SPECIMEN:

- FS1,1: left tube and ovary
- FS2,2: biopsy, bladder
- FS3,3: excision, left kidney and ureter with stent
- #4 biopsy, tap, left ureter
- #5 biopsy, medial left ureteral orifice
- #6 lateral left ureteral orifice
- #7 portion of paranephric fat
- #8 left pelvic lymph nodes
- #9 left common iliac lymph nodes
- #10 left peri-aortic lymph nodes
- #11 right pelvic lymph nodes
- #12 right common iliac and lower vena caval lymph nodes
- #13 portion of omentum

FROZEN SECTION DIAGNOSIS:

- FS1: left ovarian tumor-mucinous cystadenocarcinoma by [redacted]
- FS2: bladder biopsy-mucinous fragment of papillary transitional cell carcinoma by [redacted]
- FS3: distal ureteral margin-focal mild to moderate dysplasia.

[page 2 of 4]
GROSS DESCRIPTION:

FS1,1 Received fresh for frozen section is a 124gm. 10x6x4.2cm. left ovary and attached 4.0x1.0x0.6cm. portion of left fallopian tube. The ovarian surface is generally glistening, firm and smooth, with foci of erythema, fine granularity and fluctuance; obvious papillary surface growth is absent. Cut section reveals a partially cystic and solid parenchyma. The largest cystic space measures 8cm. in diameter and is filled almost entirely by mucoid yellow tan papillary tumor. The solid areas display a spongy cut surface, without grossly obvious scirrhous change. Cut sections through the fallopian tube are unrevealing.

The serosal aspect of the ovary is inked in green; representatives are submitted as follows:

FS1A and 1B-portions sent frozen

LFT-left fallopian tube

LO1 to LO10-left ovarian tumor

FS2,2 Received fresh for frozen section is a single 0.3x0.2x0.1cm. piece of tan soft tissue. Submitted in toto in one cassette for frozen section.

FS3,3 Received fresh for frozen section is a 118gm. 11x6.5x4.0cm. kidney and attached 25cm. long by 0.6 to 1.8cm. in circumference portion of ureter and portion of cuff of bladder. Also submitted are several portions of grossly unremarkable lobulated perinephric adipose tissue measuring 17x8x3.5cm. in aggregate. The kidney is received with the capsule already stripped; the renal surface displays persistence of fetal lobulation, coarse granularity and focal pitting. Cut section through the kidney reveals friable pink tan papillary tumor present within a lower lobe calyx and contiguous portions of the renal pelvis. The mucosal surface of most of the renal pelvis and of the attached portion of ureter shows blotchy erythema and fine granularity. Gross invasion of the renal parenchyma itself by the above mentioned papillary tumor is not noted. The renal hilum is unremarkable. Representatives are submitted as follows:

K1 to K3-kidney

T1 to T4-papillary calyceal tumor

U1 to U3-renal pelvis and proximal third, middle third and lower third of ureter

F-unremarkable perinephric fat

MU-margins of excision

FS3-portion sent frozen

#4 Received in formalin is a single 1.0x0.6x0.3cm. piece of mottled pink tan and brown soft tissue. Submitted in toto in one cassette.

#5 Received in formalin is a single 1.6x0.9x0.6cm. piece of mottled pink tan soft tissue. Sectioned and submitted in toto in one cassette.

#6 Received in formalin is a single 1.8x0.8x0.3cm. piece of mottled pink tan and brown soft tissue. Sectioned and submitted in toto in one cassette.

#7 Received in formalin is a single 11x11x1cm. piece of mottled pink tan and brown soft tissue. Each piece is externally unremarkable; serial thin sections through each reveal no discrete gross lesion. Representatives are submitted in one cassette.

[page 3 of 4]
- #8 Received in formalin are two pieces of lobulated fibroadipose tissue measuring 3.5x1.7x1.0cm. and 6.3x3.0x1.2cm. respectively. Both pieces are externally unremarkable; cut section through each reveals a total of four nodes ranging from 1.2cm. up to 3.0cm. in greatest dimension. Representatives from each node are submitted in N1 and N2.
- #9 Received in formalin is a single 5.2x2.2x0.8cm. piece of lobulated fibroadipose tissue. Externally unremarkable; cut sections reveal four clustered nodes measuring 2.5x1.5x0.6cm. in aggregate. This cluster is bisected and submitted in toto in one cassette.
- #10 Received in formalin are three pieces of lobulated fibroadipose tissue measuring 1.8x1.0x0.8cm., 2.3x1.2x1.0cm. and 8.0x1.2x0.9cm., respectively. Each piece is externally unremarkable; cut sections through each reveal a total of seven putative nodes, ranging from 0.3cm. up to 1.8cm. in greatest dimension. Representative from each node are submitted in N1 and N2.
- #11 Received in formalin are five pieces of lobulated fibroadipose tissue ranging from 2.8x1.0x0.9cm. up to 7.0x2.0x1.4cm. in size. Each piece is externally unremarkable; cut sections through each reveal a total of seven putative nodes ranging from 0.8cm. up to 3.4cm. in greatest dimension. Representatives from each node are submitted in N1 to N3.
- #12 Received in formalin is a single 2.5x1.5x0.9cm. piece of lobulated fibroadipose tissue. Externally unremarkable; cut section reveals two putative nodes measuring 0.2cm. and 1.2cm. in greatest dimension, respectively. Representatives from each are submitted together in N1.
- #13 Received fresh is a 35x25x3.0cm. portion of omental apron. Except for scattered foci of recent hemorrhage, the serosal aspect is unremarkable. Serial thin sections reveal no discrete gross lesion. A single representative is submitted.
- Total blocks: 41

DIAGNOSIS:

PS1, 1: LEFT TUBE AND OVARY:

PREDOMINANTLY SEROUS PAPILLARY ADENOCARCINOMA WITH FOCI OF CLEAR CELL ADENOFIBROMA AND FOCAL MUCINOUS ADENOCARCINOMA OF LEFT OVARY.

-LEFT FALLOPIAN TUBE - NEGATIVE FOR TUMOR.

[page 4 of 4]
[REDACTED]

FS2, 2: BIOPSY, BLADDER:

MINUTE FRAGMENTS OF PAPILLARY TRANSITIONAL CELL CARCINOMA.

FS3, 3: LEFT KIDNEY, URETER, BLADDER CUFF:

-EXOPHYTIC PAPILLARY TRANSITIONAL CELL CARCINOMA OF RENAL PELVIS, GRADE 2 (NO STROMAL INVASION) OF LEFT KIDNEY (URETERAL, VASCULAR MARGINS - NEGATIVE FOR TUMOR).

-CYSTITIS GLANDULARIS OF PELVIS AND URETER OF LEFT KIDNEY.

#4: TOP OF LEFT URETER: NEGATIVE FOR TUMOR.

#5: MEDIAL LEFT URETERAL ORIFICE:

FOCAL MILD DYSPLASIA.

#6: LATERAL, LEFT URETHRAL ORIFICE:

(BLADDER WALL TISSUE - NEGATIVE FOR TUMOR).

#7: PARANEPHRIC FAT:

ADIPOSE TISSUE - NEGATIVE FOR TUMOR.

#8: LEFT PELVIC LYMPH NODES:

FOUR LYMPH NODES - NEGATIVE FOR TUMOR.

#9: LEFT COMMON ILIAC LYMPH NODES:

FOUR LYMPH NODES - NEGATIVE FOR TUMOR.

#10: LEFT PERI-AORTIC LYMPH NODE:

SEVEN (7) LYMPH NODES - NEGATIVE FOR TUMOR.

#11: RIGHT PELVIC LYMPH NODES:

SEVEN (7) LYMPH NODES - NEGATIVE FOR TUMOR.

#12: RIGHT COMMON AND LOWER VENA CAVAL LYMPH NODE:

ONE (1) LYMPH NODE - NEGATIVE FOR TUMOR.

#13: PORTION OF OMENTUM:

NEGATIVE FOR TUMOR.

Verbal report to [REDACTED]

Conference case (#1).

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 00adeb29-6a31-4bba-add3-8f18190007d0 (TCGA-59-2349.A56064EB-651A-4A7D-B32C-5C890821E338.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).